Gene-level copy-number profile of tumor specimen C3N-08902-02 (profiled together with C3N-08902-03, C3N-08902-04) from CPTAC case C3N-08902, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 47.0 years (17,174 days).
Specimen C3N-08902-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 55d92be8-66a6-4e5d-9cdd-2c7b165b62c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-08902-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/61c2e109-d8c6-4ed6-80dd-a3dc57dac4fc

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 356; copy number 1: 32,091; copy number 2: 23,006; copy number 3: 3,287; copy number 4: 95; copy number 5: 5; copy number 6: 36; copy number 9: 1; copy number 20: 8; copy number 21: 20; copy number 22: 3.

Homozygous deletions (total copy number 0; autosomes only): 356 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,363,879–189,475,192, 70 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:129,834,698–138,253,217, 286 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,455 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,324,522–89,597,861, 7 genes, copy number 3 (within-gene range 2–3): BX119321.1, GBP6, CAPNS1P1, GBP1P1, AL596214.1, LRRC8B, AC099569.1.
- chr3:30,292,548–30,305,037, 3 genes, copy number 4: AC025614.2, AC025614.1, U3.
- chr3:30,697,661–31,637,616, 8 genes, copy number 21: AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr3:38,696,802–48,504,826, 250 genes, copy number 3–22 (broad region; genes not listed).
- chr3:62,221,249–62,926,882, 8 genes, copy number 20 (within-gene range 1–20): PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1.
- chr3:69,739,464–69,968,336, 1 gene, copy number 21 (within-gene range 1–21): MITF.
- chr3:69,999,550–70,754,573, 6 genes, copy number 21: SAMMSON, AC139700.1, UQCRHP4, MDFIC2, COX6CP6, HMGB1P36.
- chr3:78,597,239–79,767,998, 1 gene, copy number 21 (within-gene range 1–21): ROBO1.
- chr3:79,411,714–79,507,969, 2 genes, copy number 21: AC117461.1, MIR3923.
- chr3:133,015,004–133,397,775, 3 genes, copy number 3 (within-gene range 1–3): AC079942.1, TMEM108, TMEM108-AS1.
- chr3:136,250,340–136,752,403, 3 genes, copy number 3 (within-gene range 1–3): PCCB, STAG1, RNU6-1284P.
- chr3:141,051,347–142,448,062, 31 genes, copy number 3: SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P.
- chr7:88,420,167–88,756,725, 1 gene, copy number 3 (within-gene range 2–3): AC002069.2.
- chr7:88,564,793–159,233,377, 1,405 genes, copy number 3 (broad region; genes not listed).
- chr8:46,028,804–88,328,025, 617 genes, copy number 3–21 (within-gene range 2–21) (broad region; genes not listed).
- chr8:89,412,621–91,398,155, 29 genes, copy number 3: KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:92,699,742–92,879,502, 3 genes, copy number 3: FLJ46284, AC104211.2, AC117834.2.
- chr8:100,157,906–100,259,278, 1 gene, copy number 3 (within-gene range 1–3): SPAG1.
- chr8:100,165,226–100,464,613, 6 genes, copy number 3 (within-gene range 1–3): AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471.
- chr8:125,648,327–126,008,930, 1 gene, copy number 3 (within-gene range 1–3): AC016074.2.
- chr8:125,859,721–126,292,788, 1 gene, copy number 3 (within-gene range 1–3): LINC00861.
- chr8:125,951,861–145,066,685, 345 genes, copy number 3 (broad region; genes not listed).
- chr9:12,134–73,865, 5 genes, copy number 3 (within-gene range 2–3): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:26,746,953–29,318,952, 33 genes, copy number 3: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1.
- chr9:30,388,935–38,851,916, 266 genes, copy number 3 (broad region; genes not listed).
- chr10:4,024,903–12,043,170, 130 genes, copy number 3 (broad region; genes not listed).
- chr10:13,159,477–14,954,432, 36 genes, copy number 4–9: RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, SEPHS1, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C.
- chr11:56,315,144–56,776,206, 40 genes, copy number 3: OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2, OR5AR1, OR2AH1P, TMEM230P2, OR9G1, AP001803.1, OR9G3P, OR9G4, MIR6128, OR9G2P, OR5G1P.
- chr13:87,219,004–87,380,258, 2 genes, copy number 4: UBBP5, LIN28AP2.
- chr13:87,427,200–87,447,235, 1 gene, copy number 4 (within-gene range 2–4): AL360267.1.
- chr16:46,469,341–48,850,015, 65 genes, copy number 3 (broad region; genes not listed).
- chr22:15,282,557–18,861,049, 145 genes, copy number 3–4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
